Somatic mutation profile of tumor specimen SM-JU33H (aliquot 7316UP-2726) from CPTAC case C760878, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Tumor grade: G3.
Specimen SM-JU33H: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4da8c2e-88c0-4adf-8c36-66f64df33221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105278 (Blood Derived Normal), aliquot 7316UP-1843-1105278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee7ffb46-ab22-4b7c-9416-b75dc85c0268

The open-access MAF lists 106 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 22, Frame Shift Del 11, Intron 7, Nonsense Mutation 5, Splice Site 4, 5'Flank 1, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 6381/6719 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- AFF1 | c.1236_1239del p.H412Qfs*86 | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | catalogued as rs765113099; called by pindel, varscan2
- BIRC6 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs373105075; called by muse, mutect2, varscan2
- C3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 209/948 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765821415, COSV55568720; called by muse, mutect2, varscan2
- CFAP20DC | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 70/176 reads (40%) | catalogued as rs952156491; called by mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 155/480 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4A22 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 53/173 reads (31%) | catalogued as rs1182232056, COSV53738126; called by muse, mutect2, varscan2
- EDDM3A | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 83/228 reads (36%) | catalogued as rs768794732, COSV58795108, COSV58795417; called by muse, mutect2, varscan2
- EPS15L1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs750367780; called by muse, mutect2, varscan2
- FAM53A | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs559109336, COSV57401825; called by muse, mutect2, varscan2
- FAT4 | c.5053C>T p.R1685* | Nonsense Mutation (SNP) | VAF 53/209 reads (25%) | catalogued as rs760759561, COSV67882267; called by muse, mutect2, varscan2
- FRAS1 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749776166; called by muse, mutect2, varscan2
- GASK1B | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56709057, COSV99030607; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIRA | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs376487965; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NLRP4 | c.554C>G p.T185R | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV56713550; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- PCDH11Y | c.208G>A p.V70I (on ENST00000400457 / NM_032973.2; = p.V59I on NM_032971.3) | Missense Mutation (SNP) | VAF 252/349 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53082348; called by muse, mutect2, varscan2
- PROKR1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs149410240; called by muse, mutect2, varscan2
- RAD21L1 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV104369649; called by muse, mutect2, varscan2
- SLC25A21 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 43/130 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs758995590; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, mutect2, varscan2
- SNX13 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1212626732; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/622 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TLR2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 52/172 reads (30%) | catalogued as rs989773958, COSV52607172; called by muse, mutect2, varscan2
- TMEM94 | c.3433C>T p.H1145Y | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV58595309; called by muse, mutect2, varscan2
- TNFRSF14 | c.460+1G>A p.X154_splice | Splice Site (SNP) | VAF 37/102 reads (36%) | catalogued as COSV63185715; called by mutect2, varscan2
- TRPC6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437212772; called by muse, mutect2, varscan2
- UNC13B | c.278del p.P93Lfs*7 | Frame Shift Del (DEL) | VAF 91/316 reads (29%) | catalogued as COSV101037460; called by mutect2, pindel, varscan2
- ZNF407 | c.5666C>T p.T1889M | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553117551, COSV55254908; called by muse, mutect2, varscan2
- AKAP13 | c.4582G>C p.A1528P | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- AKR7A3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALPP | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO3 | c.2764-1G>A p.X922_splice | Splice Site (SNP) | VAF 122/335 reads (36%) | called by muse, mutect2, varscan2
- ARMC10 | c.434del p.N145Tfs*15 | Frame Shift Del (DEL) | VAF 2737/6828 reads (40%) | called by pindel, varscan2
- ATP1B1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRIP1 | c.3398C>A p.T1133K | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPNE1 | c.546_555del p.N183Tfs*83 (on ENST00000352393; = p.N188Tfs*83 on NM_003915.5) | Frame Shift Del (DEL) | VAF 45/201 reads (22%) | called by mutect2, pindel, varscan2
- CSNK1D | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 151/549 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EML6 | c.3237T>G p.H1079Q | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GARS1 | c.140_141del p.P47Rfs*14 | Frame Shift Del (DEL) | VAF 154/678 reads (23%) | called by pindel, varscan2
- HAUS2 | c.94-2A>G p.X32_splice | Splice Site (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2
- IGBP1P2 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGKV1D-42 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPKA | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- JPH4 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LAMA1 | c.2572T>G p.S858A | Missense Mutation (SNP) | VAF 160/420 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, varscan2
- LARP4 | c.1130_1139del p.P377Rfs*21 | Frame Shift Del (DEL) | VAF 58/323 reads (18%) | called by mutect2, pindel, varscan2
- LRRC8B | c.1531A>T p.N511Y | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MLLT10 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- MTA3 | c.1657A>G p.S553G (on ENST00000405094 / NM_001330442.2; = p.S496G on NM_001282755.1) | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR4F17 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 181/1578 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDXDC1 | c.1543_1544del p.P515* | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- PRKCH | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QKI | c.521_523del p.E174del | In Frame Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2
- QRICH2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SEC24D | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGMAR1 | c.645del p.T216Pfs*46 | Frame Shift Del (DEL) | VAF 146/515 reads (28%) | called by mutect2, pindel, varscan2
- SULF2 | c.1621del p.A541Pfs*11 | Frame Shift Del (DEL) | VAF 120/459 reads (26%) | called by mutect2, pindel, varscan2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 206/566 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEP1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- TMEM165 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPST1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 128/592 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- VPS18 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WASL | c.11T>A p.V4D | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YWHAZ | c.389_390insAACGTTACTTGGC p.E131Tfs*5 | Frame Shift Ins (INS) | VAF 39/157 reads (25%) | called by mutect2, varscan2
- ZMIZ1 | c.2822C>G p.P941R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF229 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF236 | c.4098_4099del p.N1367Lfs*17 | Frame Shift Del (DEL) | VAF 59/234 reads (25%) | called by mutect2, pindel, varscan2
- ZNF670 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP3B1 | c.1983C>T p.T661= | Silent (SNP) | VAF 119/375 reads (32%) | called by muse, mutect2, varscan2
- CAVIN1 | c.972C>T p.H324= | Silent (SNP) | VAF 152/423 reads (36%) | catalogued as rs1421562805, COSV100824606; called by muse, mutect2, varscan2
- CBFA2T3 | c.1887C>T p.S629= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as rs750626340; called by muse, mutect2, varscan2
- CYP4Z1 | c.699C>T p.N233= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as rs370015142; called by muse, mutect2, varscan2
- DPP10 | c.192G>A p.S64= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as rs201248540; called by muse, mutect2, varscan2
- FLNB | c.6114G>A p.A2038= | Silent (SNP) | VAF 200/616 reads (32%) | catalogued as rs1559730956; called by muse, mutect2, varscan2
- HMGCS2 | c.879C>T p.D293= | Silent (SNP) | VAF 110/300 reads (37%) | catalogued as rs761787433, COSV65569426; called by muse, mutect2, varscan2
- HTR1E | c.105C>G p.L35= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- MAGEA12 | c.681G>T p.V227= | Silent (SNP) | VAF 230/311 reads (74%) | called by muse, mutect2, varscan2
- MYLK3 | c.603G>A p.A201= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs781406736; called by muse, mutect2, varscan2
- OR52J3 | c.654G>A p.S218= | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as rs148600962, COSV66747742; called by muse, mutect2, varscan2
- OR8A1 | c.411T>C p.S137= | Silent (SNP) | VAF 99/234 reads (42%) | catalogued as rs538622740; called by muse, mutect2, varscan2
- OSMR | c.87T>C p.R29= | Silent (SNP) | VAF 80/276 reads (29%) | called by muse, mutect2, varscan2
- POTEJ | c.2622C>T p.D874= | Silent (SNP) | VAF 249/1004 reads (25%) | called by muse, varscan2
- PPP1R3B | c.795C>G p.S265= | Silent (SNP) | VAF 90/262 reads (34%) | catalogued as rs1268134247; called by muse, mutect2, varscan2
- PRDM9 | c.2671A>C p.R891= | Silent (SNP) | VAF 154/441 reads (35%) | called by muse, mutect2, varscan2
- PRRC2A | c.411C>T p.S137= | Silent (SNP) | VAF 83/273 reads (30%) | catalogued as rs761009382, COSV63224694; called by muse, mutect2, varscan2
- SEC14L5 | c.327C>T p.N109= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs375401992; called by muse, mutect2, varscan2
- SERHL2 | c.12C>T p.N4= | Silent (SNP) | VAF 118/477 reads (25%) | called by muse, mutect2, varscan2
- TMCC2 | c.402C>T p.Y134= | Silent (SNP) | VAF 160/433 reads (37%) | catalogued as rs77588763, COSV58005035; called by muse, mutect2, varscan2
- TMEM270 | c.678C>T p.A226= | Silent (SNP) | VAF 146/705 reads (21%) | catalogued as rs201571768; called by muse, mutect2, varscan2
- TPTE2 | c.213A>T p.V71= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- ACADM | chr1:75724665 C>T | 5'Flank (SNP) | VAF 20/64 reads (31%) | catalogued as rs1307548224; called by muse, mutect2, varscan2
- ENY2 | c.230-678C>T | Intron (SNP) | VAF 86/264 reads (33%) | called by muse, mutect2, varscan2
- FCRL5 | c.-21C>G | 5'UTR (SNP) | VAF 115/366 reads (31%) | called by muse, mutect2, varscan2
- HTN3 | c.73-34A>C | Intron (SNP) | VAF 39/113 reads (35%) | catalogued as COSV66879574; called by muse, mutect2, varscan2
- MYO10 | c.21+19724G>A | Intron (SNP) | VAF 93/262 reads (35%) | catalogued as rs772652920, COSV72454035; called by muse, mutect2, varscan2
- SERINC2 | c.39+693C>G | Intron (SNP) | VAF 76/134 reads (57%) | catalogued as rs1448575368; called by muse, mutect2, varscan2
- SNRNP200 | c.5754+39C>G | Intron (SNP) | VAF 204/478 reads (43%) | catalogued as rs746692485; called by muse, mutect2, varscan2
- TSPEAR | c.633+33G>A | Intron (SNP) | VAF 192/545 reads (35%) | catalogued as rs777838829; called by muse, mutect2, varscan2
- TTN | c.10360+1582G>A | Intron (SNP) | VAF 58/167 reads (35%) | called by muse, mutect2, varscan2
